Surgical pathology report (de-identified scan), TCGA case TCGA-G2-A2EC, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site MD Anderson, specimen TCGA-G2-A2EC-01A (Primary Tumor).

PATHOLOGY REPORT

1CA-0-3
carcinoma, urothelial, nos 8/20/3
Site: bladder, nos C67.9
lw 5/31/11

DIAGNOSIS

(A) BLADDER TUMOR:
UROTHELIAL CARCINOMA WITH NESTED FEATURES, HIGH-GRADE (GRADE 3),
EXTENSIVELY INVASIVE INTO MUSCULARIS PROPRIA, SUSPICIOUS FOR
LYMPHOVASCULAR INVASION.

Ulceration, necrosis, inflammation, and reactive stromal cells, suggestive of prior resection changes.

GROSS DESCRIPTION

(A) BLADDER TUMOR – Received is a 4.0 x 3.5 x 2.5 cm aggregate of tan-gray fibrous tissue.
The specimen is submitted entirely in A1-A8.

CLINICAL HISTORY

Bladder cancer.

UPNA Discrepancy		☒

Source: NCI Genomic Data Commons file 243a8a77-355a-4242-915e-f246c2a17bca (TCGA-G2-A2EC.77EEB2BE-B13B-41FD-B503-8C107D16FE38.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).